Gene-level copy-number profile of tumor specimen TCGA-CV-5440-01A from TCGA case TCGA-CV-5440, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 52.6 years (19,197 days).
Specimen TCGA-CV-5440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.02cde315-da7e-4d9f-9aef-199c528ac9e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5440-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bc9c412-02c6-4ef4-bd68-4392903c6510

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 205; copy number 2: 18,127; copy number 3: 14,098; copy number 4: 14,857; copy number 5: 10,279; copy number 6: 462; copy number 7: 575; copy number 8: 156; copy number 9: 866; copy number 12: 159; copy number 17: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5440-01A-01D-1510-01): tumor purity 0.69, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:105,554,035–105,653,820, 2 genes (within-gene range 0–4): AL158070.1, FKTN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12,525 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:201,620,184–203,315,871, 59 genes, copy number 6: TMEM237, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P, AC069148.1, FZD7, KIAA2012, KIAA2012-AS1, AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2.
- chr3:84,958,989–86,074,429, 5 genes, copy number 6 (within-gene range 2–6): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2.
- chr3:90,261,414–115,147,288, 303 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:115,100,423–198,222,513, 1,498 genes, copy number 5 (broad region; genes not listed).
- chr4:49,203,171–52,866,835, 43 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B.
- chr4:52,945,649–52,958,087, 1 gene, copy number 5: AC023154.1.
- chr5:58,198–4,041,764, 94 genes, copy number 5 (broad region; genes not listed).
- chr6:62,460,940–66,728,904, 32 genes, copy number 5: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:70,972–104,907,232, 1,965 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:96,309,221–140,638,283, 575 genes, copy number 7 (broad region; genes not listed).
- chr8:140,940,562–145,066,685, 193 genes, copy number 6 (broad region; genes not listed).
- chr9:14,475–68,330,626, 945 genes, copy number 5–6 (broad region; genes not listed).
- chr9:68,353,614–68,406,500, 2 genes, copy number 6: PGM5-AS1, AL161457.2.
- chr11:64,746,389–71,821,548, 343 genes, copy number 8–17 (broad region; genes not listed).
- chr11:96,092,374–96,137,827, 1 gene, copy number 5 (within-gene range 2–5): AP000779.1.
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).
- chr13:65,787,932–106,904,099, 453 genes, copy number 5–6 (broad region; genes not listed).
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5 (broad region; genes not listed).
- chr18:30,713,275–31,102,522, 6 genes, copy number 6: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2.
- chr19:21,932,958–22,010,949, 1 gene, copy number 5 (within-gene range 3–5): ZNF208.
- chr19:21,965,708–27,984,984, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:18,467,389–18,796,067, 16 genes, copy number 9: POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653.
- chr20:19,208,652–19,722,926, 4 genes, copy number 6 (within-gene range 4–6): AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1.
- chr21:43,805,758–46,665,124, 131 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
